Somatic mutation profile of tumor specimen TCGA-94-A5I4-01A (aliquot TCGA-94-A5I4-01A-11D-A26M-08) from TCGA case TCGA-94-A5I4, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Main bronchus; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.1 years (22,299 days).
Specimen TCGA-94-A5I4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2006eef1-7575-4dbf-b98b-0aad7d6a9638.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-94-A5I4-10A (Blood Derived Normal), aliquot TCGA-94-A5I4-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd8f32a0-2979-48f4-9419-865930f5c0c5

The open-access MAF lists 265 somatic variants for this specimen: 199 protein-altering or splice-affecting, 56 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 56, Nonsense Mutation 18, Frame Shift Del 5, Intron 4, Splice Site 4, RNA 4, Frame Shift Ins 2, 3'Flank 1, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.993+2T>C p.X331_splice | Splice Site (SNP) | VAF 36/59 reads (61%) | hotspot (GDC flag); catalogued as COSV52703680, COSV52798259, COSV52814192; called by muse, mutect2, varscan2
- ABCA4 | c.1758C>A p.D586E | Missense Mutation (SNP) | VAF 201/335 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100933060; called by muse, mutect2, varscan2
- ABCA8 | c.3703G>A p.D1235N | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as COSV99285124; called by muse, mutect2, varscan2
- ABCB6 | c.2084A>G p.E695G | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99202378; called by muse, mutect2, varscan2
- ACAP2 | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as COSV100461654; called by muse, mutect2, varscan2
- ACSM4 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.864); catalogued as rs1293872138, COSV68067910; called by muse, mutect2, varscan2
- ADAM2 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV99696937; called by muse, mutect2, varscan2
- ADGRB3 | c.3846C>G p.Y1282* | Nonsense Mutation (SNP) | VAF 97/151 reads (64%) | catalogued as COSV99484048; called by muse, mutect2, varscan2
- ADGRL3 | c.2972C>A p.A991E (on ENST00000506720 / NM_001322402.2; = p.A923E on NM_015236.6) | Missense Mutation (SNP) | VAF 95/281 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101546918; called by muse, mutect2, varscan2
- ADNP2 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV100080613; called by muse, mutect2, varscan2
- AGTR1 | c.619C>G p.P207A | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100836960, COSV62558901; called by muse, mutect2, varscan2
- AKAP3 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1187371918, COSV57421039; called by muse, mutect2, varscan2
- ANKRD12 | c.4258G>C p.E1420Q | Missense Mutation (SNP) | VAF 82/343 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); catalogued as COSV100040933; called by muse, mutect2, varscan2
- ANPEP | c.1688A>T p.Q563L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100262762; called by muse, mutect2, varscan2
- ASCC3 | c.971G>T p.C324F | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV100225387; called by muse, mutect2, varscan2
- ATP10A | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.105); catalogued as rs766840564, COSV63513338; called by muse, mutect2, varscan2
- ATP2C1 | c.221A>G p.K74R | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.766); catalogued as rs768572508, COSV100146393; called by muse, mutect2, varscan2
- BACH1 | c.1406C>T p.T469I | Missense Mutation (SNP) | VAF 152/239 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV99728014; called by muse, mutect2, varscan2
- BMP1 | c.2507G>T p.R836L | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs762317805, COSV100114655; called by muse, mutect2, varscan2
- BMPR2 | c.2063A>T p.H688L | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101001330; called by muse, mutect2, varscan2
- BSDC1 | c.1147G>T p.G383* | Nonsense Mutation (SNP) | VAF 55/107 reads (51%) | catalogued as rs867515163, COSV100344446; called by muse, mutect2, varscan2
- C6orf58 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100314745; called by muse, mutect2, varscan2
- CACNA1D | c.6084G>T p.E2028D (on ENST00000350061 / NM_001128840.3; = p.E2048D on NM_000720.4) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs777336747, COSV99856978; called by muse, mutect2, varscan2
- CANX | c.1556C>A p.A519E | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99910294; called by muse, mutect2, varscan2
- CATSPERB | c.3245G>T p.G1082V | Missense Mutation (SNP) | VAF 69/121 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV99830958; called by muse, mutect2, varscan2
- CCBE1 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 100/193 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV101232791, COSV67951134; called by muse, mutect2, varscan2
- CCDC150 | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99776614; called by muse, mutect2, varscan2
- CCM2L | c.1318G>T p.E440* (on ENST00000452892 / NM_001365692.1; = p.G418= on NM_080625.4) | Nonsense Mutation (SNP) | VAF 87/266 reads (33%) | catalogued as COSV99395013, COSV99395352; called by muse, mutect2, varscan2
- CCNE1 | c.277A>T p.K93* | Nonsense Mutation (SNP) | VAF 41/124 reads (33%) | catalogued as COSV99388226; called by muse, mutect2, varscan2
- CCNT1 | c.2141C>A p.P714Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99980538; called by muse, mutect2
- CD1B | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 118/222 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs1426925259, COSV100939295, COSV63805156; called by muse, mutect2, varscan2
- CDH4 | c.338G>T p.W113L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.254); catalogued as COSV100848514; called by muse, varscan2
- CHRDL1 | c.68A>T p.Q23L (on ENST00000372045; = p.Q29L on NM_145234.4) | Missense Mutation (SNP) | VAF 76/107 reads (71%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV99487815; called by muse, mutect2, varscan2
- CLNS1A | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99627962; called by muse, mutect2, varscan2
- COL19A1 | c.2568+2T>C p.X856_splice | Splice Site (SNP) | VAF 16/168 reads (10%) | catalogued as COSV59567501; called by muse, mutect2
- COL4A3 | c.2246C>A p.P749H | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs918245943, COSV101170066; called by muse, mutect2, varscan2
- COL5A3 | c.2314G>A p.A772T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as COSV99318369; called by muse, mutect2
- COLEC12 | c.1822C>A p.P608T | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV101231992; called by muse, mutect2, varscan2
- CR1 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV100887434; called by muse, mutect2, varscan2
- CSN2 | c.325T>C p.Y109H | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.187); catalogued as COSV100778749; called by muse, mutect2, varscan2
- CSPG4 | c.3103C>T p.R1035W | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1348888821, COSV100413569; called by muse, mutect2, varscan2
- CST5 | c.168C>A p.N56K | Missense Mutation (SNP) | VAF 98/320 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100489580; called by muse, mutect2, varscan2
- CTNNA2 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.063); catalogued as COSV100782237; called by muse, mutect2, varscan2
- DEPDC5 | c.2629G>A p.A877T (on ENST00000400246; = p.A946T on NM_014662.5) | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs538998618, COSV56699232; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMXL1 | c.2296G>C p.D766H | Missense Mutation (SNP) | VAF 95/173 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100223505; called by muse, mutect2, varscan2
- DNAH3 | c.8638G>A p.A2880T | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99765656; called by muse, mutect2, varscan2
- DNAH3 | c.6677C>T p.S2226L | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as COSV54504780; called by muse, mutect2, varscan2
- DNMT3B | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.161); catalogued as rs754832933, COSV99140598; called by muse, mutect2, varscan2
- DPYS | c.360G>T p.W120C | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV100679373; called by muse, mutect2, varscan2
- DYSF | c.3712G>T p.E1238* | Nonsense Mutation (SNP) | VAF 50/158 reads (32%) | catalogued as COSV50300420, COSV99245106; called by muse, mutect2, varscan2
- ENOSF1 | c.1353A>T p.E451D (on ENST00000340116 / NM_001354066.2; = p.E417D on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/500 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99200988; called by muse, mutect2, varscan2
- EPDR1 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs750207754, COSV99554150; called by muse, mutect2, varscan2
- ERICH3 | c.1717G>T p.D573Y | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100443685; called by muse, mutect2, varscan2
- FGF18 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 92/146 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs556878675, COSV51127983; called by muse, mutect2, varscan2
- FN1 | c.889C>G p.Q297E | Missense Mutation (SNP) | VAF 86/157 reads (55%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.899); catalogued as COSV100116469; called by muse, mutect2, varscan2
- FOXA2 | c.464A>G p.Y155C (on ENST00000377115 / NM_153675.3; = p.Y161C on NM_021784.5) | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101008272; called by muse, mutect2, varscan2
- FOXE1 | c.493G>C p.A165P | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV100909859; called by muse, mutect2
- FTO | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 40/111 reads (36%) | catalogued as rs200201735, COSV67111046; called by muse, mutect2, varscan2
- GABRB2 | c.1474C>T p.R492C (on ENST00000274547; = p.R454C on NM_000813.3) | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50909148; called by muse, mutect2, varscan2
- GAPVD1 | c.4246G>T p.V1416F (on ENST00000394104; = p.V1425F on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/250 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99782824; called by muse, mutect2
- GDA | c.800A>T p.K267I | Missense Mutation (SNP) | VAF 68/281 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV99428883; called by muse, mutect2, varscan2
- GFRA4 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs749853855, COSV99293855; called by muse, mutect2, varscan2
- GPR61 | c.411T>A p.N137K | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV101344399; called by muse, mutect2, varscan2
- GRIA4 | c.24T>G p.I8M | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs1437117200, COSV99229662; called by muse, mutect2, varscan2
- GUCY2C | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV99663357, COSV99664292; called by muse, mutect2, varscan2
- HDX | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 85/129 reads (66%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV52973250; called by muse, mutect2, varscan2
- HECTD4 | c.2299A>G p.K767E | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.138); catalogued as COSV100295900; called by muse, mutect2, varscan2
- HPSE2 | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 63/112 reads (56%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); catalogued as COSV100985261; called by muse, mutect2, varscan2
- HTR1B | c.490A>T p.K164* | Nonsense Mutation (SNP) | VAF 37/82 reads (45%) | catalogued as COSV100885358; called by muse, mutect2, varscan2
- IBTK | c.2463A>C p.K821N | Missense Mutation (SNP) | VAF 115/215 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV100090222; called by muse, mutect2, varscan2
- INSR | c.1942C>G p.P648A | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as COSV100251720, COSV57174085; called by muse, mutect2, varscan2
- IRAG2 | c.3838A>G p.R1280G (on ENST00000636465; = p.R325G on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/194 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100209061; called by muse, mutect2, varscan2
- ITLN1 | c.202A>T p.T68S | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV100406140; called by muse, mutect2, varscan2
- JHY | c.2123C>G p.A708G | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV99912867; called by muse, mutect2, varscan2
- KCNC2 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.924); catalogued as COSV100128421; called by muse, mutect2, varscan2
- KIF2B | c.1816G>C p.G606R | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.067); catalogued as COSV52131115, COSV99274886; called by muse, mutect2, varscan2
- LENG8 | c.1411G>T p.D471Y | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100457242; called by muse, mutect2, varscan2
- LGR6 | c.1270C>G p.L424V (on ENST00000367278 / NM_001017403.1; = p.L372V on NM_021636.3) | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99706315; called by muse, mutect2, varscan2
- LILRA4 | c.714G>C p.E238D | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV52491119, COSV99392967; called by muse, mutect2, varscan2
- LINGO1 | c.1687A>G p.M563V | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV100796313; called by muse, mutect2, varscan2
- LPA | c.4235G>A p.W1412* | Nonsense Mutation (SNP) | VAF 168/353 reads (48%) | catalogued as COSV100306340, COSV60316145; called by muse, mutect2, varscan2
- LRAT | c.321C>G p.S107R | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as COSV100312044; called by muse, mutect2, varscan2
- LRP1 | c.4468dup p.E1490Gfs*6 | Frame Shift Ins (INS) | VAF 18/118 reads (15%) | catalogued as rs139915490; called by mutect2, varscan2
- MAGEB18 | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as COSV100305346; called by muse, mutect2, varscan2
- MAGEC1 | c.2031G>T p.Q677H | Missense Mutation (SNP) | VAF 86/131 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); catalogued as rs777289996, COSV53582409; called by muse, mutect2, varscan2
- MAP2K3 | c.154A>G p.I52V (on ENST00000342679 / NM_145109.3; = p.I23V on NM_002756.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1356564972, COSV100383529; called by muse, mutect2, varscan2
- MAP3K5 | c.3526C>T p.P1176S | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.197); catalogued as COSV100752589; called by muse, mutect2, varscan2
- MAPRE2 | c.168G>T p.E56D | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT tolerated (0.82); PolyPhen benign (0.194); catalogued as COSV100290381; called by muse, mutect2, varscan2
- MARCHF4 | c.1190C>G p.P397R | Missense Mutation (SNP) | VAF 104/189 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV99814140; called by muse, mutect2, varscan2
- MBD5 | c.2878A>T p.N960Y | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101289971; called by muse, mutect2, varscan2
- MDM4 | c.925T>A p.C309S | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100914429; called by muse, mutect2, varscan2
- MLLT10 | c.3155A>C p.K1052T (on ENST00000307729 / NM_001195626.3; = p.K1027Q on NM_004641.3) | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100307627; called by muse, mutect2, varscan2
- MUC16 | c.32573G>C p.G10858A | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV101198719; called by muse, mutect2, varscan2
- MUC16 | c.31739G>A p.S10580N | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.842); catalogued as rs372342303; called by muse, mutect2, varscan2
- MUC16 | c.8346G>T p.R2782S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV101198721; called by muse, mutect2, varscan2
- MUC16 | c.623T>A p.V208E | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV101198724; called by muse, mutect2, varscan2
- MYH6 | c.5190G>T p.K1730N | Missense Mutation (SNP) | VAF 64/100 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100676367; called by muse, mutect2, varscan2
- MYO1B | c.1453A>G p.T485A | Missense Mutation (SNP) | VAF 209/510 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV100268798; called by muse, mutect2, varscan2
- NCK2 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 48/113 reads (42%) | catalogued as COSV99255391; called by muse, mutect2, varscan2
- NOL6 | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs371383324; called by muse, mutect2, varscan2
- NPHP1 | c.1430G>A p.R477H (on ENST00000393272 / NM_207181.4; = p.R478H on NM_000272.5) | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV57209622; called by muse, mutect2, varscan2
- NTPCR | c.496G>T p.V166L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100786691; called by muse, mutect2, varscan2
- NUP37 | c.827T>C p.M276T | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99195836; called by muse, mutect2, varscan2
- OR10G9 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.103); catalogued as COSV100901475; called by muse, mutect2, varscan2
- OR2M5 | c.745G>T p.G249* | Nonsense Mutation (SNP) | VAF 150/418 reads (36%) | catalogued as COSV63546441; called by muse, mutect2, varscan2
- OR4A16 | c.98A>T p.Y33F | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100125070; called by muse, mutect2, varscan2
- OR4C12 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV100078347; called by muse, mutect2, varscan2
- OR4C6 | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100051457; called by muse, mutect2, varscan2
- OR51B6 | c.845del p.P282Hfs*4 | Frame Shift Del (DEL) | VAF 24/173 reads (14%) | catalogued as COSV66512762; called by mutect2, pindel, varscan2
- OR5R1 | c.836C>G p.T279R | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100393310; called by muse, mutect2, varscan2
- OR5T3 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV100282713; called by muse, mutect2, varscan2
- OR6N2 | c.215G>T p.W72L | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100209997; called by muse, mutect2, varscan2
- OR8H3 | c.14G>T p.R5M | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV100538804, COSV57911589; called by muse, mutect2, varscan2
- OR8H3 | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV100538805; called by muse, mutect2
- PCDHA5 | c.1772C>A p.A591E | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.434); catalogued as COSV100972169; called by muse, mutect2, varscan2
- PCDHAC2 | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs782010447, COSV53850602; called by muse, mutect2, varscan2
- PCDHB7 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.181); catalogued as rs1554280317, COSV99032877, COSV99176269; called by muse, mutect2, varscan2
- PGR | c.615G>A p.W205* | Nonsense Mutation (SNP) | VAF 20/32 reads (63%) | catalogued as COSV99677595, COSV99677628; called by muse, mutect2, varscan2
- PIK3R4 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 72/115 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100768297; called by muse, mutect2, varscan2
- PKN3 | c.1643C>A p.S548Y | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV99403378; called by muse, mutect2, varscan2
- PLB1 | c.3039A>T p.R1013S | Missense Mutation (SNP) | VAF 93/249 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.912); catalogued as COSV100577910; called by muse, mutect2, varscan2
- PLCB1 | c.1006A>T p.T336S | Missense Mutation (SNP) | VAF 85/253 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100569877; called by muse, mutect2, varscan2
- PLCB4 | c.3382A>C p.K1128Q | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV99594662; called by muse, mutect2, varscan2
- PNMA3 | c.125C>A p.A42D | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV100937566; called by muse, mutect2, varscan2
- PORCN | c.848A>G p.D283G (on ENST00000326194 / NM_203475.3; = p.D272G on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as COSV100400367; called by muse, mutect2, varscan2
- POU6F2 | c.1831C>G p.R611G | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101302532; called by muse, mutect2, varscan2
- PPFIA2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.71); PolyPhen probably damaging (0.932); catalogued as COSV100332120; called by muse, mutect2, varscan2
- PRB2 | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 296/776 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.087); catalogued as COSV101231383; called by muse, mutect2, varscan2
- PRLHR | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.262); catalogued as rs1413095413; called by muse, mutect2
- PTPRA | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV99399353; called by muse, mutect2, varscan2
- RASGRP3 | c.1603C>T p.Q535* (on ENST00000402538 / NM_001349975.2; = p.Q534* on NM_015376.2 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV101274711; called by muse, mutect2, varscan2
- RBFOX1 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 118/338 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.25); catalogued as COSV100300157; called by muse, mutect2, varscan2
- RBM28 | c.1502A>G p.K501R | Missense Mutation (SNP) | VAF 132/186 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0.341); catalogued as rs757103148, COSV99775547; called by muse, mutect2, varscan2
- RDH16 | c.305G>C p.R102T | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100660076; called by muse, mutect2, varscan2
- RELN | c.6863C>G p.S2288C | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100632809; called by muse, mutect2, varscan2
- RGS6 | c.85A>C p.I29L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1566600490, COSV100665425; called by muse, mutect2, varscan2
- RNGTT | c.8A>T p.H3L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV99665906; called by muse, mutect2, varscan2
- RTN4 | c.2716G>T p.G906* | Nonsense Mutation (SNP) | VAF 74/204 reads (36%) | catalogued as COSV100462813; called by muse, mutect2, varscan2
- SCN1A | c.1137G>A p.M379I | Missense Mutation (SNP) | VAF 111/255 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57675237; called by muse, mutect2, varscan2
- SCN2A | c.605C>A p.A202E | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV51839806, COSV99330521; called by muse, mutect2, varscan2
- SETX | c.6923G>A p.R2308K | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.192); catalogued as COSV99809048; called by muse, mutect2, varscan2
- SIRPG | c.967del p.D323Mfs*9 | Frame Shift Del (DEL) | VAF 84/252 reads (33%) | catalogued as COSV53811137; called by mutect2, pindel, varscan2
- SKAP2 | c.25T>A p.S9T | Missense Mutation (SNP) | VAF 109/138 reads (79%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV100591761; called by muse, mutect2, varscan2
- SLC13A1 | c.229-2A>T p.X77_splice | Splice Site (SNP) | VAF 11/129 reads (9%) | catalogued as COSV99520575; called by muse, mutect2
- SLC18A3 | c.572T>A p.F191Y | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100339887; called by muse, mutect2, varscan2
- SLC25A10 | c.485C>A p.S162* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV100518961; called by muse, mutect2, varscan2
- SLC25A38 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 113/229 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM093168, COSV99827798; called by muse, mutect2, varscan2
- SLC39A10 | c.734A>G p.E245G | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100660545; called by muse, mutect2, varscan2
- SLC8A3 | c.2392G>A p.G798S (on ENST00000381269 / NM_183002.3; = p.G796S on NM_033262.4) | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99385361; called by muse, mutect2, varscan2
- SLC8A3 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100775997; called by muse, mutect2, varscan2
- SLCO2A1 | c.1618G>C p.V540L | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100188741; called by muse, mutect2, varscan2
- SOHLH1 | c.608G>T p.C203F | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100039919; called by muse, mutect2, varscan2
- SORL1 | c.4548C>A p.S1516R | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as COSV99493150; called by muse, mutect2, varscan2
- SPAG16 | c.1877C>A p.T626K | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV100435391; called by muse, mutect2, varscan2
- SPTBN4 | c.5430C>A p.D1810E | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100150260; called by muse, mutect2, varscan2
- SYN3 | c.454G>T p.V152L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100248569; called by muse, mutect2, varscan2
- SYNE1 | c.847C>G p.P283A (on ENST00000367255 / NM_182961.4; = p.P290A on NM_033071.3) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99556436; called by muse, mutect2, varscan2
- TAF3 | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 50/114 reads (44%) | catalogued as COSV100719932, COSV60210887; called by muse, mutect2, varscan2
- TAL2 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1041060238, COSV100482432; called by muse, mutect2, varscan2
- TARS3 | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs774454880, COSV60109069; called by muse, mutect2, varscan2
- TGS1 | c.1075G>C p.A359P | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as COSV99485177; called by muse, mutect2, varscan2
- THBS2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs769719849, COSV64678774, COSV64682665; called by muse, mutect2, varscan2
- TJP1 | c.1535A>C p.E512A | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.624); catalogued as COSV100632437; called by muse, mutect2, varscan2
- TMED3 | c.74G>T p.C25F | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.019); catalogued as COSV100229922; called by muse, mutect2, varscan2
- TMEM126B | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV100728996; called by muse, mutect2, varscan2
- TMEM163 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99925821; called by muse, mutect2, varscan2
- TMEM45B | c.332A>G p.H111R | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99859264; called by muse, mutect2, varscan2
- TMEM52B | c.524C>T p.S175L (on ENST00000381923 / NM_001079815.1; = p.S155L on NM_153022.4) | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.213); catalogued as rs748030036, COSV53727927; called by muse, mutect2, varscan2
- TNNI3 | c.119A>G p.K40R | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.948); catalogued as COSV100787867; called by muse, mutect2, varscan2
- TNNT1 | c.781G>C p.A261P | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV52572635, COSV99402744; called by muse, mutect2, varscan2
- TRMT1 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as rs1234202486, COSV99317026; called by muse, mutect2, varscan2
- TRPC4 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as COSV100156199; called by muse, mutect2, varscan2
- TTN | c.38220G>T p.Q12740H (on ENST00000591111; = p.Q5316H on NM_003319.4) | Missense Mutation (SNP) | VAF 101/230 reads (44%) | PolyPhen benign (0); catalogued as COSV100599809; called by muse, mutect2, varscan2
- TTN | c.31643T>C p.V10548A (on ENST00000591111; = p.V9621A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/143 reads (31%) | PolyPhen benign (0); catalogued as COSV100599810; called by muse, mutect2, varscan2
- TTN | c.12187A>G p.K4063E (on ENST00000591111; = p.K4017E on NM_003319.4) | Missense Mutation (SNP) | VAF 57/126 reads (45%) | catalogued as COSV100599813; called by muse, mutect2, varscan2
- TTN | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 67/208 reads (32%) | PolyPhen probably damaging (0.999); catalogued as rs781001961, COSV100599816; called by muse, mutect2, varscan2
- UBL7 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100795360; called by muse, mutect2, varscan2
- UNC13C | c.6503G>T p.W2168L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV52881971; called by muse, mutect2, varscan2
- VPS16 | c.2411A>T p.H804L | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV100988322; called by muse, mutect2, varscan2
- XIRP2 | c.9172G>T p.D3058Y (on ENST00000628543; = p.D3233Y on NM_152381.6) | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99739840; called by muse, mutect2, varscan2
- XPC | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs778771038, COSV53207716; called by muse, mutect2, varscan2
- ZADH2 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 319/545 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100463318; called by muse, mutect2, varscan2
- ZBTB16 | c.1269-2A>G p.X423_splice | Splice Site (SNP) | VAF 24/62 reads (39%) | catalogued as COSV100251126; called by muse, mutect2, varscan2
- ZBTB40 | c.3620C>G p.P1207R | Missense Mutation (SNP) | VAF 79/119 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100988845; called by muse, mutect2, varscan2
- ZFC3H1 | c.5615G>T p.G1872V | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs1462097568, COSV101110385; called by muse, mutect2
- ZNF184 | c.629A>T p.K210I | Missense Mutation (SNP) | VAF 113/199 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99279453; called by muse, mutect2, varscan2
- ZNF331 | c.272G>C p.R91T | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99466992; called by muse, mutect2, varscan2
- ZNF519 | c.277G>C p.G93R | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV101645555; called by muse, mutect2, varscan2
- ZNF750 | c.615C>A p.Y205* | Nonsense Mutation (SNP) | VAF 29/79 reads (37%) | catalogued as COSV53960706; called by muse, mutect2, varscan2
- ZNF804B | c.2369C>A p.S790* | Nonsense Mutation (SNP) | VAF 27/117 reads (23%) | catalogued as rs750196062, COSV100302429; called by muse, mutect2, varscan2
- EPB41L3 | c.1753del p.L585Cfs*16 | Frame Shift Del (DEL) | VAF 32/121 reads (26%) | called by mutect2, pindel, varscan2
- IGKV1D-8 | c.119G>T p.R40I | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- KLHL34 | c.835del p.Q279Rfs*16 | Frame Shift Del (DEL) | VAF 9/11 reads (82%) | called by mutect2, varscan2
- MRC1 | c.958A>T p.N320Y | Missense Mutation (SNP) | VAF 336/812 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC2 | c.1077dup p.K360Qfs*95 | Frame Shift Ins (INS) | VAF 35/115 reads (30%) | called by mutect2, pindel, varscan2
- SAGE1 | c.2517del p.Q840Kfs*17 | Frame Shift Del (DEL) | VAF 32/49 reads (65%) | called by mutect2, pindel, varscan2
- TNXB | c.3289G>C p.D1097H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRBV27 | c.23A>G p.Y8C | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK2 | c.4905C>A p.C1635* (on ENST00000297954 / NM_001282394.1; = p.C1598* on NM_006648.3) | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2
- ACSM1 | c.1485G>A p.A495= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs373609434, COSV99532643, COSV99533503; called by muse, mutect2, varscan2
- ACSM2A | c.1134C>A p.I378= (on ENST00000219054; = p.I299= on NM_001308169.2) | Silent (SNP) | VAF 72/259 reads (28%) | catalogued as COSV99524989, COSV99525474; called by muse, mutect2, varscan2
- ACTN2 | c.2271G>A p.E757= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs763561017, COSV100856604; called by muse, mutect2, varscan2
- ADAMTS12 | c.3891C>A p.G1297= | Silent (SNP) | VAF 123/219 reads (56%) | catalogued as COSV100710436; called by muse, mutect2, varscan2
- ADGRE3 | c.1338C>T p.L446= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV53730872, COSV99505933; called by muse, mutect2, varscan2
- ARMC3 | c.2241G>T p.L747= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as COSV99957656; called by muse, mutect2, varscan2
- ATP10A | c.2607C>T p.D869= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as rs372023252; called by muse, mutect2, varscan2
- CADPS | c.1101C>T p.L367= | Silent (SNP) | VAF 78/136 reads (57%) | catalogued as rs1242362305, COSV99336553; called by muse, mutect2, varscan2
- CC2D1A | c.1707T>C p.S569= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as COSV100528319; called by muse, mutect2, varscan2
- CHD7 | c.8388G>C p.L2796= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV101418065; called by muse, mutect2, varscan2
- COL4A2 | c.3906T>A p.G1302= | Silent (SNP) | VAF 59/102 reads (58%) | catalogued as COSV100847268; called by muse, mutect2, varscan2
- CREBBP | c.2688G>C p.G896= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as COSV52137516, COSV99269011; called by muse, mutect2, varscan2
- CRTAM | c.168C>T p.F56= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as COSV99911839; called by muse, mutect2, varscan2
- CUX2 | c.1713C>T p.I571= | Silent (SNP) | VAF 25/144 reads (17%) | catalogued as rs1456074335, COSV55644195, COSV99918947; called by muse, mutect2, varscan2
- DHTKD1 | c.2526G>A p.P842= | Silent (SNP) | VAF 164/384 reads (43%) | catalogued as rs143353830; called by muse, mutect2, varscan2
- DNAI2 | c.249G>A p.K83= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV100209629; called by muse, mutect2, varscan2
- FAM189B | c.1959C>T p.R653= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100516258, COSV59171152; called by muse, mutect2
- FAT1 | c.2127C>G p.V709= | Silent (SNP) | VAF 39/60 reads (65%) | catalogued as COSV101499154; called by muse, mutect2, varscan2
- FRMPD3 | c.639T>G p.L213= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as rs1296489560, COSV99345844; called by muse, mutect2, varscan2
- GPR149 | c.2061C>A p.I687= | Silent (SNP) | VAF 29/228 reads (13%) | catalogued as COSV67667113; called by muse, mutect2, varscan2
- HS3ST4 | c.1275C>A p.I425= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100500419; called by muse, mutect2, varscan2
- IGKV2D-29 | c.213C>A p.L71= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as rs757009109, COSV101534368; called by muse, mutect2
- IGKV6D-41 | c.39C>A p.L13= | Silent (SNP) | VAF 44/128 reads (34%) | called by muse, mutect2, varscan2
- INO80 | c.2175T>C p.S725= | Silent (SNP) | VAF 57/163 reads (35%) | catalogued as COSV100731624; called by muse, mutect2, varscan2
- ITIH2 | c.1180C>A p.R394= | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as COSV100623204; called by muse, mutect2, varscan2
- MDN1 | c.12877C>T p.L4293= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs368447804; called by muse, mutect2, varscan2
- MSI2 | c.942A>T p.I314= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as COSV99401938; called by muse, mutect2, varscan2
- MSR1 | c.747C>T p.N249= | Silent (SNP) | VAF 37/67 reads (55%) | catalogued as COSV100026761; called by muse, mutect2, varscan2
- MUC16 | c.4074C>A p.S1358= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV101198723; called by muse, mutect2, varscan2
- MUC17 | c.4416T>A p.A1472= | Silent (SNP) | VAF 91/802 reads (11%) | catalogued as rs777034883; called by muse, mutect2, varscan2
- MUC5B | c.14421C>T p.A4807= | Silent (SNP) | VAF 26/150 reads (17%) | catalogued as rs1316502555, COSV101500103; called by muse, mutect2, varscan2
- MYO7B | c.5964G>A p.K1988= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as rs773409928, COSV100264308; called by muse, mutect2, varscan2
- NCOA1 | c.3588A>T p.A1196= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as COSV99945458; called by muse, mutect2, varscan2
- NPAP1 | c.1869A>G p.P623= | Silent (SNP) | VAF 50/144 reads (35%) | catalogued as rs1446484361, COSV100274925; called by muse, mutect2, varscan2
- OR2M5 | c.744G>T p.V248= | Silent (SNP) | VAF 149/422 reads (35%) | catalogued as COSV100822757; called by muse, mutect2, varscan2
- OR5A2 | c.483A>G p.T161= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs750724216, COSV100119688; called by muse, mutect2, varscan2
- OR6K6 | c.861G>A p.L287= (on ENST00000368144; = p.L263= on NM_001005184.1) | Silent (SNP) | VAF 76/138 reads (55%) | catalogued as COSV100933698; called by muse, mutect2, varscan2
- OR8A1 | c.537C>T p.D179= | Silent (SNP) | VAF 29/154 reads (19%) | catalogued as COSV99420395; called by muse, mutect2, varscan2
- OXER1 | c.1271G>A p.*424= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as rs1217516214, COSV99685281; called by muse, mutect2, varscan2
- PCDHB9 | c.732G>A p.Q244= | Silent (SNP) | VAF 31/44 reads (70%) | called by muse, mutect2, varscan2
- POLE | c.1356C>T p.P452= | Silent (SNP) | VAF 63/160 reads (39%) | catalogued as COSV100265664; called by muse, mutect2, varscan2
- RASGRP4 | c.1107G>A p.L369= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV99498457; called by muse, mutect2, varscan2
- RASSF7 | c.999T>C p.S333= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100272426; called by mutect2, varscan2
- RERGL | c.339T>A p.A113= | Silent (SNP) | VAF 53/193 reads (27%) | catalogued as COSV99967816; called by muse, mutect2, varscan2
- SLC7A4 | c.1305G>A p.Q435= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100298560; called by muse, mutect2, varscan2
- SLC9C2 | c.1230A>G p.V410= | Silent (SNP) | VAF 53/117 reads (45%) | catalogued as COSV100876620; called by muse, mutect2, varscan2
- SNRPD3 | c.279A>C p.S93= | Silent (SNP) | VAF 47/166 reads (28%) | catalogued as COSV99307449; called by muse, mutect2, varscan2
- SRRM2 | c.4719T>G p.L1573= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as COSV100070425; called by muse, mutect2, varscan2
- TCEAL2 | c.648C>G p.A216= | Silent (SNP) | VAF 63/102 reads (62%) | catalogued as COSV100216252; called by muse, mutect2, varscan2
- TRAPPC9 | c.2286G>A p.L762= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs1251249505, COSV101226930; called by muse, mutect2, varscan2
- TRIM63 | c.519T>C p.C173= | Silent (SNP) | VAF 46/79 reads (58%) | catalogued as COSV100958140; called by muse, mutect2, varscan2
- TRIOBP | c.2676C>A p.P892= | Silent (SNP) | VAF 108/302 reads (36%) | catalogued as COSV100730707; called by muse, mutect2, varscan2
- TXNRD2 | c.1380G>T p.V460= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV101265933; called by muse, mutect2, varscan2
- WIPF1 | c.48A>T p.A16= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV99768177; called by muse, mutect2, varscan2
- XIRP2 | c.1917C>G p.T639= (on ENST00000628543; = p.T814= on NM_152381.6) | Silent (SNP) | VAF 83/199 reads (42%) | catalogued as COSV99739838; called by muse, mutect2, varscan2
- ZNF611 | c.81G>T p.R27= | Silent (SNP) | VAF 104/188 reads (55%) | catalogued as rs1404414045, COSV100160115; called by muse, mutect2, varscan2
- ARHGAP39 | c.2522-3523G>A | Intron (SNP) | VAF 39/186 reads (21%) | catalogued as rs1460385080, COSV99430492; called by muse, mutect2, varscan2
- CNOT11 | chr2:101273004 G>A | 3'Flank (SNP) | VAF 103/258 reads (40%) | called by muse, mutect2, varscan2
- FOXP1 | c.180+254A>G | Intron (SNP) | VAF 39/61 reads (64%) | catalogued as COSV100561264; called by muse, mutect2, varscan2
- MIR520C | n.47A>G | RNA (SNP) | VAF 59/96 reads (61%) | called by muse, mutect2, varscan2
- PKD1L2 | n.746C>A | RNA (SNP) | VAF 36/65 reads (55%) | called by muse, mutect2, varscan2
- REXO1L1P | n.1487C>A | RNA (SNP) | VAF 8/24 reads (33%) | called by muse, varscan2
- SNORD116-24 | n.51G>T | RNA (SNP) | VAF 119/472 reads (25%) | called by muse, mutect2, varscan2
- TTLL8 | c.938+414C>T | Intron (SNP) | VAF 64/187 reads (34%) | catalogued as COSV99838110; called by muse, mutect2, varscan2
- TTN | c.10361-3827G>A | Intron (SNP) | VAF 88/207 reads (43%) | catalogued as rs746166300, COSV60035643; called by muse, mutect2, varscan2
- XIRP2 | c.-62G>A | 5'UTR (SNP) | VAF 79/193 reads (41%) | catalogued as COSV99738592; called by muse, mutect2, varscan2
